Somatic mutation profile of tumor specimen MBCproject_0095_T2_WES (aliquot MBCproject_0095_T2_WES_1) from CMI case MBCproject_0095, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 32.1 years (11,708 days).
Specimen MBCproject_0095_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ff05945-4be7-4f71-8f1a-e98f0fb37591.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCproject_0095_SALIVA (Saliva), aliquot MBCproject_0095_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/461367ba-5b2f-4a85-bd26-5413c892ee83

The open-access MAF lists 145 somatic variants for this specimen: 93 protein-altering or splice-affecting, 35 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 35, Intron 9, Frame Shift Del 5, Nonsense Mutation 4, In Frame Del 4, 3'UTR 3, Splice Site 2, Splice Region 2, 5'Flank 2, RNA 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4516G>A p.E1506K | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852671, CM011262; ClinVar: pathogenic; called by muse, mutect2
- ABHD1 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as rs371626040; called by muse, mutect2, varscan2
- ATRX | c.7170delinsAT p.Y2391Lfs*3 | Frame Shift Ins (INS) | VAF 30/269 reads (11%) | catalogued as COSV100971120, COSV64874611; called by mutect2*, pindel, varscan2*
- CABP4 | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV100351495; called by muse, mutect2
- CCN3 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1433992895; called by muse, mutect2
- CCNT1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.684); catalogued as rs1565619651; called by muse, mutect2, varscan2
- CREB3L3 | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 65/409 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50249569; called by muse, mutect2, varscan2
- DAAM2 | c.2804G>T p.R935M (on ENST00000274867 / NM_001201427.2; = p.R934M on NM_015345.3) | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51420930; called by muse, mutect2, varscan2
- DYRK1B | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392981608; called by muse, mutect2, varscan2
- ERVMER34-1 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 50/185 reads (27%) | catalogued as COSV66920659; called by muse, mutect2, varscan2
- FOXD3 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV100942875; called by muse, mutect2, varscan2
- FPGT | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs376392962; called by mutect2, varscan2
- IRAK1 | c.1712G>C p.S571T | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs1346294230; called by muse, mutect2
- ITGA2B | c.471del p.V158* | Frame Shift Del (DEL) | VAF 22/159 reads (14%) | catalogued as COSV99289125; called by mutect2, pindel, varscan2
- KDM6B | c.3532C>T p.R1178W | Missense Mutation (SNP) | VAF 121/555 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs779500605; called by muse, mutect2, varscan2
- MYO3A | c.4490G>A p.R1497Q | Missense Mutation (SNP) | VAF 36/391 reads (9%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as rs375133744; called by muse, mutect2
- NOS1 | c.4036G>C p.E1346Q | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV57606555; called by muse, mutect2, varscan2
- PLEKHA7 | c.2094C>G p.F698L | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63044368; called by muse, mutect2, varscan2
- PLXNA4 | c.2626del p.V876Sfs*29 | Frame Shift Del (DEL) | VAF 77/421 reads (18%) | catalogued as COSV58170160; called by mutect2, pindel, varscan2
- POTEE | c.2479T>C p.F827L | Missense Mutation (SNP) | VAF 81/846 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as rs1192825275; called by muse, mutect2, varscan2
- PRDX3 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 58/417 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs151214527; called by muse, mutect2, varscan2
- PSG7 | c.738C>G p.I246M | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.888); catalogued as COSV101343268; called by muse, varscan2
- RGS7 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs749609576, COSV100470752, COSV58543385; called by muse, mutect2, varscan2
- SHISA9 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.244); catalogued as rs746874108, COSV101428445; called by muse, mutect2, varscan2
- SLC25A48 | c.541G>T p.A181S (on ENST00000650267; = p.A127S on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.475); catalogued as rs1561551503, COSV50849263, COSV99192157; called by muse, mutect2, varscan2
- TBC1D24 | c.601G>C p.V201L | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV53547918; called by muse, mutect2, varscan2
- TCHHL1 | c.2078G>T p.G693V | Missense Mutation (SNP) | VAF 36/357 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.149); catalogued as COSV64287006; called by muse, mutect2
- TEKT3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 113/513 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs1241081916, COSV58628129; called by muse, mutect2, varscan2
- THAP5 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 75/1034 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1308920868; called by muse, mutect2
- TP53 | c.293del p.P98Lfs*25 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | catalogued as COSV52850165; called by mutect2, pindel, varscan2
- TULP3 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 124/240 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs151311529; called by muse, mutect2, varscan2
- UBR4 | c.14098C>A p.P4700T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1252320822; called by muse, mutect2
- ADD1 | c.516A>T p.R172S | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADGRB2 | c.3234C>G p.Y1078* | Nonsense Mutation (SNP) | VAF 34/163 reads (21%) | called by muse, mutect2, varscan2
- ATF5 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 68/434 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, varscan2
- BZW2 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- C4BPA | c.663T>G p.N221K | Missense Mutation (SNP) | VAF 61/335 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CD109 | c.525G>T p.L175F | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); called by muse, mutect2
- CDC37L1 | c.499A>G p.R167G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CLIC6 | c.1708G>C p.G570R (on ENST00000360731 / NM_001317009.2; = p.G552R on NM_053277.3) | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- COL14A1 | c.4832A>C p.Q1611P | Missense Mutation (SNP) | VAF 51/691 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2
- CORIN | c.522_533del p.F175_L178del | In Frame Del (DEL) | VAF 57/400 reads (14%) | called by mutect2, pindel, varscan2
- FLNA | c.4195_4202del p.K1399Lfs*4 | Frame Shift Del (DEL) | VAF 74/388 reads (19%) | called by mutect2, pindel, varscan2
- FLNA | c.3153_3158dup p.V1052_P1053dup | In Frame Ins (INS) | VAF 32/222 reads (14%) | called by mutect2, varscan2
- GDF1 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- GLCE | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- HMCN1 | c.4200+2T>A p.X1400_splice | Splice Site (SNP) | VAF 33/285 reads (12%) | called by muse, mutect2, varscan2
- KDR | c.379_414del p.A127_I138del | In Frame Del (DEL) | VAF 31/270 reads (11%) | called by mutect2, pindel
- KRCC1 | c.11C>G p.S4* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | called by muse, varscan2
- KRT15 | c.581+8C>T | Splice Region (SNP) | VAF 55/372 reads (15%) | called by muse, mutect2, varscan2
- LCT | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 70/722 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2
- LRP1B | c.10661C>A p.S3554Y | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- LRWD1 | c.998A>C p.H333P | Missense Mutation (SNP) | VAF 52/495 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- MAGIX | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.1); called by muse, mutect2
- MINK1 | c.3424G>A p.A1142T | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MPO | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MTM1 | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 53/675 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYH15 | c.150G>A p.G50= | Splice Region (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- NME9 | c.610C>G p.L204V (on ENST00000333911 / NM_001349024.2; = p.L143V on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2
- NOS1 | c.2395G>T p.V799L | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOS1 | c.1405C>A p.Q469K | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- NPTX2 | c.345_353del p.D115_R118delinsE | In Frame Del (DEL) | VAF 36/236 reads (15%) | called by mutect2, pindel*, varscan2
- OPTN | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- OR6N1 | c.543C>G p.F181L | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDHGB5 | c.1452_1483del p.Y485Gfs*22 | Frame Shift Del (DEL) | VAF 85/418 reads (20%) | called by mutect2, pindel
- PDGFD | c.547T>C p.W183R | Missense Mutation (SNP) | VAF 69/466 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POSTN | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POU6F2 | c.1719G>T p.K573N | Missense Mutation (SNP) | VAF 17/539 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- PPP1R9A | c.1148T>G p.V383G | Missense Mutation (SNP) | VAF 45/364 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RECQL5 | c.924G>T p.E308D | Missense Mutation (SNP) | VAF 40/601 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.173); called by muse, mutect2
- SAMD4B | c.1366_1395del p.T456_P465del | In Frame Del (DEL) | VAF 35/268 reads (13%) | called by mutect2, pindel
- SCX | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.031); called by muse, varscan2
- SELL | c.233T>G p.V78G (on ENST00000650983; = p.V65G on NM_000655.5) | Missense Mutation (SNP) | VAF 45/743 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- SEMA3A | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- SLC25A43 | c.900C>G p.Y300* | Nonsense Mutation (SNP) | VAF 42/448 reads (9%) | called by muse, mutect2
- SLC2A14 | c.426A>T p.E142D | Missense Mutation (SNP) | VAF 52/736 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by muse, mutect2
- SMARCAL1 | c.2154G>T p.L718F | Missense Mutation (SNP) | VAF 23/312 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2
- SNIP1 | c.576G>C p.R192S | Missense Mutation (SNP) | VAF 51/355 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRP54 | c.837A>G p.I279M | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.217); called by muse, mutect2
- SUOX | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TEX55 | c.1235C>A p.T412N | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TMBIM1 | c.645C>G p.D215E | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TMCO3 | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- TRPM4 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TTC13 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, varscan2
- VPS13D | c.5428A>C p.I1810L | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- VWF | c.7771-1G>A p.X2591_splice | Splice Site (SNP) | VAF 114/876 reads (13%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZFHX4 | c.5725G>C p.A1909P | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); called by muse, mutect2
- ZKSCAN4 | c.1072A>T p.I358F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF208 | c.2542C>G p.L848V | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ZNF318 | c.3143C>G p.T1048S | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF556 | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 34/383 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2
- ABCA12 | c.5073C>G p.G1691= (on ENST00000272895 / NM_173076.3; = p.G1373= on NM_015657.3) | Silent (SNP) | VAF 49/423 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS1 | c.570G>A p.R190= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as rs1387866029; called by muse, mutect2
- ASB10 | c.1378C>T p.L460= (on ENST00000420175 / NM_001142459.2; = p.L445= on NM_080871.4) | Silent (SNP) | VAF 44/371 reads (12%) | called by muse, mutect2, varscan2
- B3GALNT1 | c.468C>G p.T156= | Silent (SNP) | VAF 22/204 reads (11%) | called by muse, mutect2, varscan2
- BCAN | c.843T>C p.G281= | Silent (SNP) | VAF 120/367 reads (33%) | called by muse, mutect2, varscan2
- CFAP54 | c.1734A>C p.S578= | Silent (SNP) | VAF 24/170 reads (14%) | called by muse, mutect2, varscan2
- CFAP57 | c.1183C>T p.L395= | Silent (SNP) | VAF 63/426 reads (15%) | called by muse, mutect2, varscan2
- CLIP2 | c.261G>C p.V87= | Silent (SNP) | VAF 47/356 reads (13%) | called by muse, mutect2, varscan2
- COL28A1 | c.1656C>T p.D552= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as rs751915529, COSV68082134; called by muse, mutect2, varscan2
- DLG5 | c.1735C>T p.L579= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as rs973789490, COSV64947057; called by muse, mutect2, varscan2
- EEFSEC | c.720G>A p.V240= | Silent (SNP) | VAF 22/362 reads (6%) | called by muse, mutect2
- GOLGA6L22 | c.393T>C p.A131= | Silent (SNP) | VAF 137/573 reads (24%) | called by muse, mutect2, varscan2
- GRAMD1B | c.51G>A p.T17= | Silent (SNP) | VAF 53/308 reads (17%) | catalogued as COSV59201939; called by muse, mutect2, varscan2
- KIF26B | c.1743C>T p.N581= | Silent (SNP) | VAF 42/246 reads (17%) | catalogued as rs748806574; called by muse, mutect2, varscan2
- KRTAP26-1 | c.96C>A p.T32= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as rs1421857524; called by muse, varscan2
- LGI3 | c.888G>T p.V296= | Silent (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- LYST | c.3720C>T p.D1240= | Silent (SNP) | VAF 35/233 reads (15%) | called by muse, mutect2, varscan2
- MEN1 | c.1425G>A p.P475= | Silent (SNP) | VAF 229/899 reads (25%) | catalogued as rs1060503795, COSV53641026; ClinVar: likely benign; called by muse, mutect2, varscan2
- MSX1 | c.550C>T p.L184= | Silent (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- MUC4 | c.10026C>A p.T3342= | Silent (SNP) | VAF 63/642 reads (10%) | catalogued as rs879089592; called by muse, mutect2
- MYBPC3 | c.3661C>T p.L1221= | Silent (SNP) | VAF 36/347 reads (10%) | called by muse, mutect2, varscan2
- MYOD1 | c.333C>A p.R111= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- OR1K1 | c.669A>T p.A223= | Silent (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- OR5A1 | c.336G>T p.L112= | Silent (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1509G>T p.L503= | Silent (SNP) | VAF 429/776 reads (55%) | called by muse, mutect2, varscan2
- PPP4R3B | c.93C>T p.Y31= | Silent (SNP) | VAF 37/480 reads (8%) | called by muse, mutect2
- PROX1 | c.120G>C p.T40= | Silent (SNP) | VAF 55/453 reads (12%) | catalogued as COSV54779863; called by muse, mutect2, varscan2
- PSG7 | c.594C>G p.T198= | Silent (SNP) | VAF 67/555 reads (12%) | called by muse, mutect2, varscan2
- PTGR2 | c.756G>C p.L252= | Silent (SNP) | VAF 43/243 reads (18%) | called by muse, mutect2
- RADIL | c.1899C>T p.A633= | Silent (SNP) | VAF 42/334 reads (13%) | catalogued as rs1048550759; called by muse, mutect2, varscan2
- SDK1 | c.5346C>T p.N1782= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as rs778420128, COSV67364111; called by muse, mutect2, varscan2
- TMEM64 | c.378C>G p.V126= | Silent (SNP) | VAF 123/330 reads (37%) | called by muse, mutect2, varscan2
- VPS54 | c.1783C>T p.L595= | Silent (SNP) | VAF 30/266 reads (11%) | called by muse, varscan2
- WNK2 | c.108G>T p.P36= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- ZNF783 | c.213G>T p.T71= | Silent (SNP) | VAF 52/329 reads (16%) | catalogued as COSV100954210, COSV100954273; called by muse, mutect2, varscan2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 6/22 reads (27%) | catalogued as rs190105354; called by muse, varscan2
- AZIN1 | chr8:102864451 C>T | 5'Flank (SNP) | VAF 30/92 reads (33%) | catalogued as rs894194981; called by muse, mutect2, varscan2
- BTNL8 | c.787+28G>C | Intron (SNP) | VAF 42/401 reads (10%) | called by muse, mutect2, varscan2
- C4BPB | c.410-1237C>G | Intron (SNP) | VAF 65/376 reads (17%) | called by muse, mutect2, varscan2
- CHADL | c.8+35T>G | Intron (SNP) | VAF 26/157 reads (17%) | called by muse, mutect2, varscan2
- FAM169B | n.684A>T | RNA (SNP) | VAF 32/279 reads (11%) | called by muse, mutect2, varscan2
- LHFPL3 | c.-29C>A | 5'UTR (SNP) | VAF 14/92 reads (15%) | catalogued as rs1160349350; called by muse, varscan2
- MIA2 | c.1955-10T>G | Intron (SNP) | VAF 14/116 reads (12%) | called by muse, varscan2
- MYOM1 | c.4686-37A>T | Intron (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- PIGF | c.546+605C>T | Intron (SNP) | VAF 30/172 reads (17%) | catalogued as rs1461461063; called by muse, mutect2, varscan2
- POLR3A | c.1186-41G>C | Intron (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- PRKCG | c.*49G>C | 3'UTR (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- SLC22A20P | n.1592C>G | RNA (SNP) | VAF 41/291 reads (14%) | called by muse, mutect2, varscan2
- SLC9C1 | c.*20G>T | 3'UTR (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- SQLE | c.291+317T>C | Intron (SNP) | VAF 35/240 reads (15%) | catalogued as rs1269631949; called by muse, mutect2, varscan2
- TMEM135 | c.*3830C>G | 3'UTR (SNP) | VAF 43/321 reads (13%) | called by muse, mutect2, varscan2
- TXNRD1 | c.1882-2296G>C | Intron (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
